Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7438, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7438-01A (Primary Tumor).

(A) LEFT PARTIAL GLOSSECTOMY:

POORLY DIFFERENTIATED SQUAMOUS CARCINOMA WITH EXTENSIVE PERINEURAL
INVASION. PRESENCE OF VASCULAR AND LYMPHATIC INVASION.
THICKNESS 1.3 CM. TUMOR CLOSE TO DEEP MARGIN.

(B) SUPERIOR MARGIN:

Squamous mucosa, no tumor present.

(C) ANTERIOR TONGUE MARGIN:

Squamous mucosa, no tumor present.

(D) INTERIOR FLOOR OF MOUTH MARGIN:

Squamous mucosa, no tumor present.

(E) POSTERIOR TONSILLAR PILLAR MARGIN:

Squamous mucosa, no tumor present.

GROSS DESCRIPTION

(A) LEFT PARTIAL GLOSSECTOMY - A segment of mucosa and skeletal muscle with overall measurements of 4.5 x 2.5 x 1.5 cm. A central ulcer 1.5 x 1.0 x 0.8 cm is noted. The mucosa and deep skeletal muscle margin is grossly uninvolved. Specimen submitted sequentially under A1 to A10.

(B) SUPERIOR MARGIN - A strip of tan-pink, glistening tissue (2.2 x 0.4 x 0.3 cm). Submitted for frozen section in B.

*FS/DX: NO TUMOR PRESENT.

(C) ANTERIOR TONGUE MARGIN - A strip of tan-pink, glistening tissue (2.5 x 0.4 x 0.3 cm). Submitted in C.

*FS/DX: NO TUMOR PRESENT.

(D) INFERIOR FLOOR OF MOUTH MARGIN - A strip of tan-pink, glistening tissue (3.8 x 0.3 x 0.2 cm). Submitted in D for frozen section.

*FS/DX: NO TUMOR PRESENT.

(E) POSTERIOR TONSILLAR PILLAR MARGIN - A strip of tan-pink, glistening tissue (1.7 x 0.5 x 0.4 cm). Submitted for frozen in E.

*FS/DX: NO TUMOR PRESENT.

SNOMED CODES

M-80703 T-53000

Source: NCI Genomic Data Commons file 10e52b43-3c1c-475a-b734-efb1c08cea7b (TCGA-CV-7438.A2272C4D-55E5-4791-B9C8-A2DE9631E65A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).